Gene-level copy-number profile of tumor specimen MP2PRT-PARKZX-TMP1-A from MP2PRT case MP2PRT-PARKZX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.0 years (4,739 days).
Specimen MP2PRT-PARKZX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 217bc7c6-6cc7-42a6-92d7-a28f959b7222.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PARKZX-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,256 have no estimate.
https://portal.gdc.cancer.gov/files/11aa7331-beea-44af-99f8-3856c5b4cc72

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 81; copy number 1: 197; copy number 2: 42,599; copy number 3: 12,822; copy number 4: 2,619; copy number 5: 49.

Homozygous deletions (total copy number 0; autosomes only): 81 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,239,580–38,340,998, 17 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,359,162, 4 genes (within-gene range 0–2): TRGV5P, TRGV5, TRGV4, TRGV3.
- chr9:20,999,509–23,438,700, 60 genes: HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 49 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:21,852,558–22,482,959, 48 genes, copy number 5 (within-gene range 3–5): TRAV8-3, TRAV13-1, TRAV12-2, TRAV8-4, TRAV8-5, TRAV13-2, TRAV14DV4, TRAV9-2, TRAV15, AC245505.1, TRAV12-3, TRAV8-6, TRAV16, TRAV17, TRAV18, TRAV19, AC245505.2, TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2.
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.

Autosomal genes at a single copy (total copy number 1): 197. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
